Surgical pathology report (de-identified scan), TCGA case TCGA-BB-4223, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-4223-01A (Primary Tumor).

RG PATH REPORT
LECTION DATE/TIME:

FINAL DIAGNOSIS

Pathologist:

1. SUPERIOR MUCOSAL MARGIN (BX.): SALIVARY GLAND, NEGATIVE FOR TUMOR.

2. LATERAL MARGIN (BX.): ORAL MUCOSA, NEGATIVE FOR TUMOR.

3. INFERIOR MARGIN (BX.): ORAL MUCOSA, NEGATIVE FOR TUMOR.

4. MEDIAL MARGIN (BX.): ORAL MUCOSA, NEGATIVE FOR TUMOR.

5. TOOTH (EXTRACTION): TOOTH (GROSS DIAGNOSIS).

6. LEFT NECK (MODIFIED DISSECTION):

LEVEL I: METASTATIC CARCINOMA INVOLVING ONE (1) OF SEVEN (7) LYMPH NODES. HISTOLOGICALLY UNREMARKABLE SALIVARY GLAND.

LEVEL II: METASTATIC CARCINOMA INVOLVING TWO (2) OF NINE (9) LYMPH NODES. EXTRACAPSULAR EXTENSION IS IDENTIFIED.

LEVEL III: METASTATIC CARCINOMA INVOLVING ONE (1) OF SEVENTEEN (17) LYMPH NODES. HISTOLOGICALLY UNREMARKABLE SKELETAL MUSCLE.

LEVEL IV: NINE (9) LYMPH NODES AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

LEVEL V: TEN (10) LYMPH NODES, NEGATIVE FOR TUMOR.

IN TOTAL, METASTATIC CARCINOMA INVOLVES FOUR (4) OF FIFTY-TWO (52) LYMPH NODES.

7. LEFT TONSIL AND SOFT PALATE (EXCISION): INFILTRATING POORLY DIFFERENTIATED, SQUAMOUS CELL CARCINOMA (3 CM) EXTENDING TO A DEPTH OF 3 CM WITH INVASION OF DEEP SKELETAL MUSCLE. INFILTRATING CARCINOMA IS PRESENT WITHIN 1 MM OF THE DEEP MARGIN. ALL OTHER SURGICAL MARGINS ARE NEGATIVE FOR TUMOR. EXTENSIVE ANGIOLYMPHATIC INVASION IS IDENTIFIED.

CGA-BB-4223

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB PROCEDURES PERFORMED AT:

Source: NCI Genomic Data Commons file 0cb9de0e-62b0-4efe-be50-b29072d01d19 (TCGA-BB-4223.E936C1DB-CA96-4B1A-9A68-B01F487E1EE8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).